Surgical pathology report (de-identified scan), TCGA case TCGA-ZS-A9CF, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Tayside Tissue Bank, specimen TCGA-ZS-A9CF-01A (Primary Tumor).

[page 1 of 2]
Date Recvd

Issued

PRIMARY / PREVIOUS MALIGNANCY FOR

Nature of Specimen(s)

1. Portal vein lymph node.
2. Right lobe of liver.

MALE

Clinical Information Supplied

DATE OF PROCUREMENT

History of deranged LFTs during routine blood tests. Asymptomatic. Space occupying lesion right lobe of liver on ultrasound and CT scan. Presumed diagnosis - liver cell adenoma/well differentiated hepatocellular carcinoma/benign lesion.

Macro Report

1. Fatty tissue 45x27x17mm containing a lymph node 32mm in maximum dimension.
2. The specimen consists of a liver resection 108x86x72mm with attached gallbladder 92mm in maximum dimension. On sectioning the liver there is a well demarcated tan to yellow coloured tumour nodule measuring 58mm in maximum dimension. Large blood vessels are seen within the lesion but there is no obvious central scar. It appears well encapsulated on gross examination. The lesion extends to within approximately 5mm of the medial surgical resection margin on gross examination.

Micro Report

1. Section shows a reactive lymph node.
2. Section shows a tumour nodule made up of cords and trabeculae of round to polygonal cells with eosinophilic cytoplasm. The nuclei are rather variable in appearance and tend to be darker in staining characteristics than the surrounding liver. There is a moderate degree of nuclear pleomorphism and some very large atypical forms are seen focally. Mitotic activity is high and there are obvious abnormal mitotic figures with some evidence of increased cell death (apoptosis).

Although there is a clear tumour capsule tumour cells are seen microscopically to infiltrate the capsule and, in one area, there is vascular invasion within the capsule. Immunohistochemistry

Page 1 of 2

ICD-O-3

Carcinoma, hepatocellular NOS

8170/3

S.L. Liver C22.0

Dr 5/19/14

ACKNOWLEDGEMENT OF RECEIPT	
WARD SECRETARY	DOCTOR

[page 2 of 2]
Date Recvd

Date Issued

shows that the tumour cells express HepPar1 and show a distinct canalicular pattern of staining with CD10. Staining with MIB1 confirms a high proportion of cells in cell cycle. The normal reticulin framework of the liver is largely absent in the tumour.

The appearances are those of a moderately differentiated (grade 2) hepatocellular carcinoma. Surgical excision is complete. Importantly, there is heavy haemosiderin pigmentation of the macroscopically apparently normal liver. This is almost certainly due to haemochromatosis, though there is no evidence of cirrhosis. It is important that genetic testing is performed on the family.

Summary

Hepatocellular carcinoma arising in liver showing features of haemochromatosis.

Signature of Pathologist(s)

Page 2 of 2

ACKNOWLEDGEMENT OF RECEIPT			
WARD SECRETARY		DOCTOR	
Primary			
Criteria	W 2/3/14	Yes	No
Primary Tumour Site Discrepancy			✓

Source: NCI Genomic Data Commons file 1d006b54-420f-452c-8231-b54e9ec6d576 (TCGA-ZS-A9CF.B6FCD13D-3DC8-4997-A5A3-3C5D71728436.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).